Gene-level copy-number profile of tumor specimen ALCH-B2YF-TTP1-A from ALCHEMIST case ALCH-B2YF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.1 years (26,346 days).
Specimen ALCH-B2YF-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b90da8c5-d4a0-47b4-8b91-47333d7ffb22.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2YF-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/1b3ccbaf-3add-4fb6-9cce-cff552b2a57e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 145; copy number 1: 8,271; copy number 2: 49,488; copy number 3: 974; copy number 4: 16; copy number 5: 3; copy number 6: 6.

Homozygous deletions (total copy number 0; autosomes only): 56 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:6,443,034–6,447,006, 1 gene (within-gene range 0–1): AL031848.1.
- chr2:10,021,578–10,040,663, 2 genes: AC104794.4, AC104794.3.
- chr2:24,825,610–24,826,717, 1 gene (within-gene range 0–2): AC012073.1.
- chr3:130,099,092–130,111,472, 1 gene (within-gene range 0–2): FAM86HP.
- chr6:44,209,766–44,234,142, 3 genes: RN7SL811P, MYMX, SLC29A1.
- chr7:76,972,679–77,004,308, 2 genes (within-gene range 0–2): AC114737.1, DTX2P1.
- chr8:12,095,176–12,099,536, 1 gene: DEFB108D.
- chr9:93,058,688–93,085,133, 1 gene: SUSD3.
- chr9:124,481,236–124,507,420, 1 gene: NR5A1.
- chr9:124,853,417–124,861,981, 2 genes: WDR38, RPL35.
- chr10:50,676,743–50,686,326, 1 gene: NUTM2HP.
- chr12:166,856–182,399, 1 gene (within-gene range 0–2): AC007406.3.
- chr12:34,208,415–34,249,958, 2 genes (within-gene range 0–2): DUX4L27, AK6P1.
- chr15:92,779,757–92,781,492, 1 gene (within-gene range 0–2): AC106028.3.
- chr15:99,416,584–99,435,160, 2 genes: AC015660.3, AC015660.1.
- chr16:28,591,943–28,597,050, 1 gene: SULT1A2.
- chr17:17,303,335–17,347,663, 1 gene: NT5M.
- chr17:30,702,504–30,702,775, 1 gene: RN7SL316P.
- chr17:30,738,182–30,740,275, 1 gene (within-gene range 0–1): AC127024.8.
- chr17:49,939,122–49,939,819, 1 gene: AC027801.3.
- chr17:63,695,888–63,702,670, 2 genes (within-gene range 0–2): LIMD2, AC046185.3.
- chr17:81,189,593–81,222,999, 2 genes: CEP131, AC027601.2.
- chr19:1,815,248–1,848,483, 4 genes (within-gene range 0–3): REXO1, AC012615.2, MIR1909, AC012615.6.
- chr19:1,905,372–1,926,013, 2 genes (within-gene range 0–2): SCAMP4, ADAT3.
- chr19:11,221,083–11,241,943, 2 genes (within-gene range 0–2): AC011472.4, ANGPTL8.
- chr19:41,114,432–41,128,381, 1 gene: CYP2F1.
- chr20:38,425,083–38,442,169, 5 genes: SNORA71B, SNORA71A, SNORA71C, SNORA71D, SNORA71.
- chr22:18,833,694–18,861,049, 3 genes (within-gene range 0–6): E2F6P1, AC008132.1, BCRP7.
- chr22:19,045,256–19,061,843, 4 genes (within-gene range 0–2): Y_RNA, DGCR11, AC004461.1, AC004461.2.
- chr22:35,380,361–35,394,214, 1 gene: HMOX1.
- chr22:37,080,068–37,082,847, 1 gene (within-gene range 0–2): AL022314.1.
- chr22:41,922,032–41,926,806, 2 genes: TNFRSF13C, MIR378I.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:612,553–626,078, 2 genes, copy number 6: IRF7, CDHR5.
- chr19:1,241,746–1,244,825, 1 gene, copy number 6: ATP5F1D.
- chr19:1,275,530–1,279,244, 1 gene, copy number 6: FAM174C.
- chr22:38,111,495–38,216,507, 3 genes, copy number 5–6: PLA2G6, AL022322.2, MAFF.
- chr22:38,231,320–38,232,248, 2 genes, copy number 5 (within-gene range 3–5): AL020993.1, RN7SL704P.

Autosomal genes at a single copy (total copy number 1): 5,525. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
